Somatic mutation profile of tumor specimen MP2PRT-PARJWA-TMP1-A (aliquot MP2PRT-PARJWA-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARJWA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,097 days).
Specimen MP2PRT-PARJWA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff6e0ab3-15b0-43ba-81e1-d4ccd7e8bde6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARJWA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARJWA-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4a0ab7b-d370-4b27-8d6f-987aac9cc831

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Frame Shift Ins 2, Frame Shift Del 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1177_1178insTGGGCCAGGGGGCCGC p.K393Mfs*38 | Frame Shift Ins (INS) | VAF 43/331 reads (13%) | called by mutect2, pindel*, varscan2
- IGHV4-59 | c.347_348insCCCAACCGAG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 43/246 reads (17%) | called by mutect2, pindel, varscan2
- SEMA6C | c.1142del p.L381Cfs*13 | Frame Shift Del (DEL) | VAF 224/426 reads (53%) | called by mutect2, pindel*, varscan2
- TRAM1L1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- BCL11B | c.1917G>T p.A639= (on ENST00000357195 / NM_001282237.2; = p.A568= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/213 reads (21%) | called by muse, mutect2, varscan2
- CACNA1E | c.6660A>G p.Q2220= (on ENST00000367573 / NM_001205293.3; = p.Q2177= on NM_000721.4) | Silent (SNP) | VAF 377/728 reads (52%) | called by muse, mutect2, varscan2
- CCNB3 | c.2220C>A p.A740= | Silent (SNP) | VAF 157/590 reads (27%) | called by muse, mutect2, varscan2
- PGAP3 | c.651C>T p.I217= | Silent (SNP) | VAF 106/461 reads (23%) | called by muse, mutect2, varscan2
- PLCL1 | c.2634C>T p.I878= | Silent (SNP) | VAF 100/277 reads (36%) | catalogued as rs145792334; called by muse, mutect2, varscan2
- PRKN | c.1083+3430G>A | Intron (SNP) | VAF 106/437 reads (24%) | called by muse, varscan2
